Somatic mutation profile of tumor specimen TCGA-63-6202-01A (aliquot TCGA-63-6202-01A-11D-1817-08) from TCGA case TCGA-63-6202, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA.
Specimen TCGA-63-6202-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 064d34fd-862c-4b7b-9a68-c0632b8f67fa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-63-6202-10A (Blood Derived Normal), aliquot TCGA-63-6202-10A-01D-1817-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/610bf8d1-fcef-45d5-a0ac-726b1402608f

The open-access MAF lists 371 somatic variants for this specimen: 297 protein-altering or splice-affecting, 67 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 254, Silent 67, Nonsense Mutation 14, Splice Site 11, Frame Shift Del 7, RNA 4, Splice Region 4, Frame Shift Ins 3, In Frame Del 2, 3'Flank 2, 5'Flank 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL1A2 | c.1991G>T p.G664V | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs72658154, CM011306, COSV51960181; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.183A>T p.Q61H | Missense Mutation (SNP) | VAF 34/83 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RAG1 | c.1331C>T p.A444V | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as rs199474685, CM010072, COSV55024826; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.473G>T p.R158L | Missense Mutation (SNP) | VAF 36/94 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs587782144, CM102353, CM165595, CM994513, COSV52676395, COSV52678258, COSV52680378, COSV53545833; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.5089A>G p.S1697G | Missense Mutation (SNP) | VAF 64/178 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.696); catalogued as rs1286057280, COSV70032457; called by muse, mutect2, varscan2
- ABCC8 | c.1915C>G p.Q639E | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.041); catalogued as COSV56852254; called by muse, mutect2, varscan2
- ACSF3 | c.1163G>C p.R388P | Missense Mutation (SNP) | VAF 39/186 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.429); catalogued as COSV58079107, COSV58082470; called by muse, mutect2, varscan2
- ACVR1B | c.1136G>T p.R379L | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99231384; called by muse, mutect2, varscan2
- ADAM19 | c.2383C>A p.P795T | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.946); catalogued as COSV57432284; called by muse, mutect2, varscan2
- ADAM33 | c.566G>C p.G189A | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT tolerated (0.83); PolyPhen benign (0.114); catalogued as COSV62935202; called by muse, mutect2, varscan2
- ADAMTS13 | c.1363G>T p.G455C | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.736); catalogued as rs587613923, COSV63023633; called by muse, mutect2, varscan2
- ADAMTSL1 | c.298A>T p.K100* | Nonsense Mutation (SNP) | VAF 41/132 reads (31%) | catalogued as COSV52817892; called by muse, mutect2, varscan2
- ADCY5 | c.793C>A p.P265T | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV71901465; called by muse, mutect2, varscan2
- ADGRF4 | c.276C>A p.S92R | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs774783551, COSV51952175, COSV51957577; called by muse, mutect2, varscan2
- ADGRV1 | c.10834G>A p.D3612N | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.985); catalogued as COSV67983972; called by muse, mutect2, varscan2
- AKAP11 | c.1838G>T p.S613I | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as COSV50297817, COSV99213412; called by muse, mutect2, varscan2
- ALDH18A1 | c.493G>T p.G165* | Nonsense Mutation (SNP) | VAF 11/67 reads (16%) | catalogued as COSV100973122; called by muse, mutect2, varscan2
- ANK3 | c.8501C>T p.A2834V | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.025); catalogued as COSV55063852; called by muse, varscan2
- ANK3 | c.8500G>T p.A2834S | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV55063860; called by muse, varscan2
- ARG1 | c.251T>A p.V84E | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51581217; called by muse, mutect2, varscan2
- ARID1A | c.2879-1G>C p.X960_splice | Splice Site (SNP) | VAF 23/60 reads (38%) | catalogued as COSV61372173, COSV61380279; called by muse, mutect2, varscan2
- ARID1A | c.2879G>T p.G960V | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV61380291; called by muse, mutect2, varscan2
- ASAP1 | c.1518G>T p.L506= | Splice Region (SNP) | VAF 66/154 reads (43%) | catalogued as COSV63050209; called by muse, mutect2
- ATG2B | c.3724C>T p.L1242F | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55890823; called by muse, mutect2, varscan2
- AXDND1 | c.2025G>T p.M675I | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as COSV62643984, COSV62651437; called by muse, mutect2, varscan2
- B3GAT1 | c.148G>A p.G50S | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as COSV56998265; called by muse, mutect2, varscan2
- BCL11A | c.1372G>A p.E458K (on ENST00000335712 / NM_001365609.1; = p.E492K on NM_018014.4) | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV59632607; called by muse, mutect2
- C6orf15 | c.871G>T p.G291C | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV52538690; called by muse, mutect2, varscan2
- C6orf201 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV60985132; called by muse, mutect2, varscan2
- C7 | c.1133G>T p.R378I | Missense Mutation (SNP) | VAF 104/320 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV57475746; called by muse, mutect2, varscan2
- C7orf33 | c.197G>A p.R66K | Missense Mutation (SNP) | VAF 33/143 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.162); catalogued as COSV61023300; called by muse, mutect2, varscan2
- CACNA2D4 | c.128C>A p.A43D | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.052); catalogued as rs1476433399, COSV54952258; called by muse, mutect2, varscan2
- CAMK1G | c.64A>G p.T22A | Missense Mutation (SNP) | VAF 5/105 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.01); catalogued as COSV50522973; called by muse, mutect2
- CAND1 | c.3508G>A p.D1170N | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.957); catalogued as COSV73389660; called by muse, mutect2, varscan2
- CATSPERD | c.287C>G p.P96R | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101062600, COSV67535206; called by muse, mutect2, varscan2
- CCDC115 | c.315G>T p.K105N | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.919); catalogued as COSV52091989; called by muse, mutect2, varscan2
- CCL26 | c.186G>T p.V62= | Splice Region (SNP) | VAF 17/93 reads (18%) | catalogued as COSV50013709; called by muse, mutect2, varscan2
- CCNE1 | c.138G>T p.M46I | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV52904804; called by muse, mutect2, varscan2
- CD177 | c.995T>A p.L332H | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.525); catalogued as COSV65121648; called by mutect2, varscan2
- CD27 | c.652A>T p.R218* | Nonsense Mutation (SNP) | VAF 10/170 reads (6%) | catalogued as COSV56947339; called by muse, mutect2
- CDH18 | c.485G>T p.G162V | Missense Mutation (SNP) | VAF 59/201 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56931583; called by muse, mutect2, varscan2
- CDH18 | c.484G>A p.G162R | Missense Mutation (SNP) | VAF 59/202 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56903868; called by muse, mutect2, varscan2
- CDH23 | c.2855A>T p.E952V | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV54939221; called by muse, mutect2, varscan2
- CEP170 | c.2257C>A p.Q753K | Missense Mutation (SNP) | VAF 16/276 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs772579241, COSV60510437; called by muse, mutect2
- CEP350 | c.4556A>T p.H1519L | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.21); PolyPhen benign (0.037); catalogued as COSV62604418; called by muse, mutect2, varscan2
- CEP41 | c.1014G>T p.K338N | Missense Mutation (SNP) | VAF 68/314 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as COSV56220226; called by muse, mutect2, varscan2
- CFAP61 | c.3514-1G>T p.X1172_splice | Splice Site (SNP) | VAF 27/171 reads (16%) | catalogued as COSV55633983; called by muse, mutect2, varscan2
- CFAP61 | c.3514G>T p.E1172* | Nonsense Mutation (SNP) | VAF 29/173 reads (17%) | catalogued as COSV55633991; called by muse, mutect2, varscan2
- CHIT1 | c.554C>A p.P185Q | Missense Mutation (SNP) | VAF 50/149 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV55147473; called by muse, mutect2, varscan2
- CHRNB4 | c.355A>C p.N119H | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55716515; called by muse, varscan2
- CNGB3 | c.1514C>G p.T505R | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.052); catalogued as COSV60691782; called by muse, mutect2, varscan2
- CNTN6 | c.2065C>A p.P689T | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as COSV63176558; called by muse, mutect2, varscan2
- CNTNAP2 | c.949G>T p.G317* | Nonsense Mutation (SNP) | VAF 18/123 reads (15%) | catalogued as COSV62197909, COSV62201663; called by muse, mutect2, varscan2
- CNTNAP2 | c.950G>T p.G317V | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62201670; called by muse, mutect2, varscan2
- COL28A1 | c.823C>G p.Q275E | Missense Mutation (SNP) | VAF 43/309 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.062); catalogued as COSV68082780, COSV68082833; called by muse, mutect2, varscan2
- COL5A3 | c.3028G>A p.G1010S | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53412920; called by muse, mutect2
- COL6A6 | c.2647G>T p.G883C | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV62028229; called by muse, varscan2
- COL9A1 | c.1133T>C p.V378A | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.79); PolyPhen benign (0.1); catalogued as rs1338024383, COSV57886236; called by muse, mutect2, varscan2
- CPOX | c.697G>T p.D233Y | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as COSV51638832; called by muse, mutect2, varscan2
- CPXM2 | c.2139G>C p.R713S | Missense Mutation (SNP) | VAF 32/227 reads (14%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as COSV53864331, COSV99581002; called by muse, mutect2, varscan2
- CPZ | c.227G>T p.S76I (on ENST00000360986 / NM_001014447.3; = p.S65I on NM_003652.3) | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59923688; called by muse, mutect2, varscan2
- CR2 | c.1921C>G p.Q641E | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.1); catalogued as rs755692271, COSV100889689, COSV65508193; called by muse, mutect2, varscan2
- CRB1 | c.572C>T p.A191V | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV66343072; called by muse, mutect2, varscan2
- CSF1R | c.2071C>A p.Q691K | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT tolerated (0.73); PolyPhen benign (0.129); catalogued as COSV53836797; called by muse, mutect2, varscan2
- CTNNA2 | c.1137+2T>C p.X379_splice | Splice Site (SNP) | VAF 16/191 reads (8%) | catalogued as COSV58158508; called by muse, mutect2
- CTNNA3 | c.1144A>T p.I382L | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as rs1312731220, COSV65594431; called by muse, mutect2, varscan2
- CTSD | c.1072-1G>T p.X358_splice | Splice Site (SNP) | VAF 4/44 reads (9%) | catalogued as COSV99362311; called by muse, mutect2
- DCLRE1B | c.797C>T p.P266L | Missense Mutation (SNP) | VAF 63/138 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV65813035; called by muse, mutect2, varscan2
- DIO2 | c.188T>A p.V63D | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV70445387; called by muse, mutect2, varscan2
- DNAH11 | c.13357C>G p.L4453V | Missense Mutation (SNP) | VAF 50/279 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.072); catalogued as COSV60961752; called by muse, mutect2, varscan2
- DOCK2 | c.3511G>T p.V1171L | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV56965284; called by muse, mutect2, varscan2
- DOCK7 | c.2603G>C p.G868A | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV52010148; called by muse, mutect2, varscan2
- DPP6 | c.899C>A p.T300K (on ENST00000377770 / NM_001364500.2; = p.T238K on NM_001936.5) | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.091); catalogued as COSV59622626; called by muse, mutect2, varscan2
- DSE | c.1234A>T p.R412* | Nonsense Mutation (SNP) | VAF 8/75 reads (11%) | catalogued as COSV59064914; called by muse, mutect2, varscan2
- DYRK1B | c.1747G>T p.A583S | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as COSV59914195, COSV59914274; called by muse, mutect2, varscan2
- ECI2 | c.293C>A p.A98D (on ENST00000380118 / NM_206836.3; = p.A68D on NM_006117.2) | Missense Mutation (SNP) | VAF 88/222 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV60987019; called by muse, mutect2, varscan2
- EFCAB6 | c.1984-2A>G p.X662_splice | Splice Site (SNP) | VAF 22/76 reads (29%) | catalogued as COSV53065580; called by muse, mutect2, varscan2
- EFL1 | c.1652A>G p.Q551R | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as COSV51606674; called by muse, mutect2, varscan2
- ELP1 | c.864G>T p.K288N | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65898303; called by muse, mutect2, varscan2
- ERC1 | c.97C>T p.R33C | Missense Mutation (SNP) | VAF 36/166 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs571730696, COSV61693366, COSV61697937; called by muse, mutect2, varscan2
- ERN2 | c.1585G>T p.G529W | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99891145; called by muse, mutect2, varscan2
- EXPH5 | c.4841G>A p.R1614K | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.31); catalogued as COSV56203860; called by muse, mutect2
- FAM71B | c.610G>C p.A204P | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.045); catalogued as COSV100261817, COSV57229619; called by muse, mutect2, varscan2
- FAM83D | c.1583A>T p.N528I | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as COSV54157914; called by muse, mutect2, varscan2
- FBN2 | c.6709T>A p.C2237S | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV52521745; called by muse, mutect2
- FBXL7 | c.905A>T p.H302L | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.484); catalogued as COSV61647909; called by muse, mutect2
- FEZ1 | c.127C>A p.L43I | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.196); catalogued as COSV54031362, COSV99630464; called by muse, mutect2, varscan2
- FHOD3 | c.1189C>G p.R397G | Missense Mutation (SNP) | VAF 44/172 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.011); catalogued as COSV57176984, COSV57181563; called by muse, mutect2, varscan2
- FLG | c.9382C>A p.H3128N | Missense Mutation (SNP) | VAF 130/644 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as COSV64243253; called by muse, mutect2, varscan2
- FLG | c.2911C>T p.R971C | Missense Mutation (SNP) | VAF 23/658 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as COSV64243257, COSV64247172; called by muse, mutect2
- FMN2 | c.538G>T p.D180Y | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60435301, COSV60453655; called by muse, mutect2, varscan2
- GABRA2 | c.497G>A p.C166Y | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62916083; called by muse, mutect2, varscan2
- GABRG3 | c.527A>T p.H176L | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.73); PolyPhen benign (0.05); catalogued as COSV61521695; called by muse, mutect2, varscan2
- GABRQ | c.1232C>A p.P411Q | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.025); catalogued as rs782128839, COSV100941232, COSV64782499; called by muse, mutect2, varscan2
- GAK | c.3682G>T p.E1228* | Nonsense Mutation (SNP) | VAF 14/25 reads (56%) | catalogued as COSV58506045; called by muse, mutect2, varscan2
- GALNT12 | c.539G>T p.R180I | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.602); catalogued as COSV66662744; called by muse, mutect2, varscan2
- GDF9 | c.211G>T p.V71F | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV51526573; called by muse, mutect2, varscan2
- GNA11 | c.394A>G p.I132V | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as COSV50020539; called by muse, mutect2, varscan2
- GNAT1 | c.745A>G p.I249V | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1252882654, COSV51697739; called by muse, mutect2, varscan2
- GRIK5 | c.1269+1G>T p.X423_splice | Splice Site (SNP) | VAF 29/64 reads (45%) | catalogued as COSV53480439, COSV99490402; called by muse, mutect2, varscan2
- GRM8 | c.2139G>T p.W713C | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58836434; called by muse, mutect2, varscan2
- HERC1 | c.14268G>C p.W4756C | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV71248490; called by muse, mutect2, varscan2
- IBA57 | c.643G>T p.D215Y | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV64511236; called by muse, mutect2, varscan2
- ICE2 | c.2869A>T p.M957L | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV55031924; called by muse, mutect2, varscan2
- IFNL3 | c.207C>G p.C69W | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV69830043; called by muse, mutect2, varscan2
- IGKV1-12 | c.298C>A p.L100M | Missense Mutation (SNP) | VAF 91/459 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.885); catalogued as rs1361049406; called by muse, mutect2, varscan2
- IL1R2 | c.16G>T p.V6L | Missense Mutation (SNP) | VAF 33/389 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV60207748; called by muse, mutect2
- IMPG2 | c.2236G>C p.D746H | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV51980155; called by muse, mutect2, varscan2
- INTU | c.1244A>G p.Y415C | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777571454, COSV58872541; called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.1498A>G p.I500V (on ENST00000485419 / NM_001197113.1; = p.I424V on NM_014575.3) | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as rs373474163, COSV61848076; called by muse, mutect2, varscan2
- ITGB4 | c.120G>T p.E40D | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.935); catalogued as rs753782989, COSV52328125; called by muse, mutect2, varscan2
- KANK4 | c.331C>G p.P111A | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.026); catalogued as COSV62987401, COSV62990078; called by muse, mutect2, varscan2
- KCNH1 | c.589C>A p.Q197K | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.225); catalogued as COSV55087285; called by muse, mutect2, varscan2
- KIF2B | c.1880C>A p.A627D | Missense Mutation (SNP) | VAF 50/123 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.241); catalogued as COSV52128271, COSV52131947; called by muse, mutect2, varscan2
- KLC4 | c.1658G>T p.G553V | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.109); catalogued as COSV52436635; called by muse, mutect2, varscan2
- KMT2A | c.7838A>G p.K2613R | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV63287514; called by muse, mutect2, varscan2
- KRI1 | c.1558C>G p.P520A | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV57264974; called by muse, mutect2, varscan2
- KRT71 | c.821C>A p.T274N | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.155); catalogued as COSV57291279; called by muse, mutect2, varscan2
- L1TD1 | c.349G>T p.G117W | Missense Mutation (SNP) | VAF 72/182 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as COSV63133624; called by muse, mutect2, varscan2
- LCK | c.230A>T p.D77V | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.703); catalogued as COSV60741026; called by muse, mutect2, varscan2
- LCT | c.1736C>G p.A579G | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV51551632, COSV99930574; called by muse, mutect2, varscan2
- LILRB1 | c.934G>T p.G312W (on ENST00000427581; = p.G276W on NM_006669.6) | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61119147; called by muse, mutect2, varscan2
- LILRB2 | c.124G>T p.G42W | Missense Mutation (SNP) | VAF 24/191 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100079201; called by muse, mutect2, varscan2
- LMAN2 | c.435G>A p.G145= | Splice Region (SNP) | VAF 3/36 reads (8%) | catalogued as COSV57424897; called by muse, mutect2
- LMTK3 | c.986G>A p.R329H | Missense Mutation (SNP) | VAF 29/144 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.595); catalogued as COSV54313569; called by muse, mutect2, varscan2
- LOX | c.740G>T p.S247I | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV50238510; called by muse, mutect2, varscan2
- LRP1B | c.9317C>A p.T3106K | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67236089; called by muse, mutect2, varscan2
- LRRC7 | c.2252C>T p.A751V (on ENST00000651989 / NM_001370785.2; = p.A718V on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 63/186 reads (34%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.031); catalogued as COSV50414558, COSV50485589; called by muse, mutect2, varscan2
- LRRIQ3 | c.313C>T p.H105Y | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV63042473; called by muse, mutect2, varscan2
- LTBP2 | c.1490G>T p.G497V | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as COSV56209743; called by muse, mutect2, varscan2
- MAGEB1 | c.483T>G p.F161L | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs755250563, COSV66775939; called by mutect2, varscan2
- MAGEC2 | c.1095G>T p.M365I | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV55999895; called by muse, mutect2, varscan2
- MAP2K6 | c.565G>T p.A189S | Missense Mutation (SNP) | VAF 91/278 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV63006436; called by muse, mutect2, varscan2
- MAPKAP1 | c.1346G>T p.S449I (on ENST00000265960 / NM_001006617.3; = p.S413I on NM_024117.3) | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.882); catalogued as COSV56369629; called by muse, mutect2, varscan2
- MARK2 | c.1696C>T p.P566S (on ENST00000402010 / NM_001039469.2; = p.P511S on NM_004954.5) | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.047); catalogued as COSV59284909; called by muse, mutect2, varscan2
- MASP1 | c.1439T>C p.L480P | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56224621; called by muse, mutect2, varscan2
- MRPL3 | c.515C>T p.P172L | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs148638602; called by muse, mutect2, varscan2
- MSGN1 | c.206G>T p.C69F | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV55263073; called by muse, mutect2, varscan2
- MUC16 | c.17863C>A p.L5955I | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); catalogued as rs368655863, COSV67474320, COSV67475097; called by muse, mutect2, varscan2
- MUC16 | c.16789G>T p.V5597L | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.01); catalogued as rs751532991, COSV67465644, COSV67474328; called by muse, mutect2, varscan2
- MUC16 | c.13820G>T p.S4607I | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.635); catalogued as COSV67468434, COSV67474337; called by muse, mutect2, varscan2
- MYH4 | c.5250G>T p.Q1750H | Missense Mutation (SNP) | VAF 65/166 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as COSV55120218; called by muse, mutect2, varscan2
- MYO1H | c.324G>T p.M108I | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.373); catalogued as COSV60447052; called by muse, mutect2, varscan2
- MYO5A | c.4559C>T p.A1520V | Missense Mutation (SNP) | VAF 46/232 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV62558447, COSV62561434; called by muse, mutect2, varscan2
- MYO5A | c.3091A>C p.N1031H | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as COSV62561444, COSV62562838; called by muse, mutect2, varscan2
- NAA10 | c.667G>C p.D223H | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.647); catalogued as COSV63132562; called by muse, mutect2, varscan2
- NAV3 | c.240C>G p.S80R | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); catalogued as COSV57088099, COSV99890605; called by muse, mutect2, varscan2
- NEK4 | c.2004G>T p.Q668H | Missense Mutation (SNP) | VAF 74/209 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV51781043; called by muse, mutect2, varscan2
- NEUROD6 | c.206A>T p.D69V | Missense Mutation (SNP) | VAF 47/268 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV51772107; called by muse, mutect2, varscan2
- NEXMIF | c.1043G>T p.R348L | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV50041827; called by muse, mutect2, varscan2
- NFXL1 | c.2421+1G>T p.X807_splice | Splice Site (SNP) | VAF 21/78 reads (27%) | catalogued as COSV67431937; called by muse, mutect2, varscan2
- NKX2-5 | c.753C>A p.N251K | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV61298463, COSV61299356; called by muse, mutect2
- NLRC4 | c.129C>A p.C43* | Nonsense Mutation (SNP) | VAF 20/210 reads (10%) | catalogued as COSV100707330, COSV61593234; called by muse, mutect2
- NMBR | c.368A>T p.Q123L | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV57801902; called by muse, mutect2, varscan2
- NOX5 | c.1076G>T p.G359V | Missense Mutation (SNP) | VAF 33/145 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV52990731; called by muse, mutect2, varscan2
- NPAP1 | c.369C>G p.F123L | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.446); catalogued as COSV100275579, COSV61508156; called by muse, mutect2, varscan2
- OGDHL | c.1477-1G>T p.X493_splice | Splice Site (SNP) | VAF 13/110 reads (12%) | catalogued as COSV65103156; called by muse, mutect2, varscan2
- OGDHL | c.1390G>T p.A464S | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.186); catalogued as COSV65103162; called by muse, mutect2, varscan2
- OR10Z1 | c.680G>T p.R227M | Missense Mutation (SNP) | VAF 113/304 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV63525262; called by muse, mutect2, varscan2
- OR13C8 | c.932T>A p.L311Q | Missense Mutation (SNP) | VAF 39/73 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as COSV58611457; called by muse, mutect2, varscan2
- OR2J3 | c.572C>T p.S191L | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as rs755458130, COSV65848628, COSV65848702; called by muse, mutect2
- OR2L13 | c.617T>C p.L206P | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100813924, COSV63554950; called by muse, mutect2, varscan2
- OR2M4 | c.393G>C p.Q131H | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.401); catalogued as COSV60708577; called by muse, mutect2, varscan2
- OR2T8 | c.683C>A p.S228Y | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100178183; called by muse, mutect2
- OR4C6 | c.873G>T p.E291D | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.936); catalogued as COSV58604659, COSV58605317; called by muse, mutect2, varscan2
- OR5W2 | c.708A>T p.K236N | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV60616677; called by muse, mutect2, varscan2
- OR8G5 | c.481G>A p.G161S | Missense Mutation (SNP) | VAF 60/244 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.165); catalogued as COSV100422347; called by muse, mutect2, varscan2
- OR8K1 | c.31G>T p.A11S | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.01); catalogued as COSV54403007; called by muse, mutect2, varscan2
- OR9A2 | c.146G>T p.C49F | Missense Mutation (SNP) | VAF 25/187 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.878); catalogued as COSV63306766; called by muse, mutect2, varscan2
- PAQR4 | c.533G>A p.G178E | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.239); catalogued as COSV51891717; called by muse, mutect2, varscan2
- PCDHA13 | c.103G>A p.V35I | Missense Mutation (SNP) | VAF 56/152 reads (37%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.078); catalogued as rs1554173824, COSV56506589; called by muse, mutect2, varscan2
- PCDHGB5 | c.618T>G p.S206R | Missense Mutation (SNP) | VAF 16/167 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.022); catalogued as COSV53968950; called by muse, mutect2
- PCYT1B | c.911A>T p.Q304L | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.053); catalogued as COSV63265364; called by muse, mutect2, varscan2
- PDCD11 | c.4360A>T p.S1454C | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.221); catalogued as COSV63934288; called by muse, mutect2
- PDE10A | c.452C>A p.P151H | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV100604913; called by muse, mutect2, varscan2
- PDE10A | c.451C>A p.P151T | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.478); catalogued as COSV63099124; called by muse, mutect2, varscan2
- PDE6B | c.46C>A p.P16T | Missense Mutation (SNP) | VAF 8/123 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV55327472; called by muse, mutect2
- PI15 | c.420G>C p.K140N | Missense Mutation (SNP) | VAF 25/188 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52642333; called by muse, mutect2, varscan2
- PIK3C2A | c.2746G>T p.A916S | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs573278976, COSV56404082, COSV99074586; called by muse, mutect2, varscan2
- PIKFYVE | c.424A>G p.M142V | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as rs779990042, COSV52243281; called by muse, mutect2, varscan2
- PIKFYVE | c.2677A>T p.I893F | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.02); catalogued as COSV52243294; called by muse, mutect2, varscan2
- PIWIL1 | c.1821G>T p.Q607H | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55348112; called by muse, mutect2, varscan2
- PLAAT1 | c.574G>T p.D192Y (on ENST00000650797; = p.D87Y on NM_020386.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53229985, COSV53231805, COSV99290587; called by muse, mutect2, varscan2
- PLCB4 | c.1533C>A p.H511Q | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.027); catalogued as COSV53805573; called by muse, mutect2, varscan2
- PLCZ1 | c.929G>T p.R310I | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.797); catalogued as COSV56852972, COSV56854250; called by muse, mutect2, varscan2
- PODNL1 | c.453G>A p.M151I | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs150464916; called by muse, mutect2
- POLQ | c.5392C>T p.P1798S | Missense Mutation (SNP) | VAF 48/119 reads (40%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV51754355; called by muse, mutect2, varscan2
- POM121L12 | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.573); catalogued as rs565383229, COSV68693234; called by muse, mutect2, varscan2
- POP1 | c.2375G>T p.S792I | Missense Mutation (SNP) | VAF 83/216 reads (38%) | SIFT tolerated (0.48); PolyPhen benign (0.013); catalogued as COSV62893156; called by muse, mutect2, varscan2
- POR | c.1456G>A p.G486S | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.845); catalogued as rs373347327; called by muse, mutect2
- POTEF | c.2359C>A p.H787N | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.959); catalogued as COSV62541765; called by muse, mutect2, varscan2
- PPP2R2B | c.933G>T p.M311I (on ENST00000394409; = p.M377I on NM_181674.2) | Missense Mutation (SNP) | VAF 58/151 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.408); catalogued as COSV60754434; called by muse, mutect2, varscan2
- PRG4 | c.245G>A p.R82K | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV66624389; called by muse, mutect2
- PRICKLE2 | c.1962G>T p.Q654H (on ENST00000295902; = p.Q598H on NM_198859.4) | Missense Mutation (SNP) | VAF 62/267 reads (23%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.771); catalogued as COSV55767535; called by muse, mutect2, varscan2
- PTGFR | c.1070C>T p.A357V | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.01); catalogued as COSV66115452; called by muse, mutect2, varscan2
- PTPRF | c.1132G>A p.G378S | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as rs1186911250, COSV63442827; called by muse, mutect2, varscan2
- REG1B | c.498C>A p.N166K | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as COSV59306256; called by muse, mutect2, varscan2
- RHOBTB1 | c.352G>T p.V118L | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as COSV61959035; called by muse, mutect2, varscan2
- RIMS2 | c.3688G>A p.V1230I | Missense Mutation (SNP) | VAF 15/330 reads (5%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.007); catalogued as COSV51692554; called by muse, mutect2
- ROBO2 | c.2272G>T p.V758F | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.481); catalogued as COSV59917024; called by muse, mutect2, varscan2
- ROCK2 | c.319C>T p.Q107* | Nonsense Mutation (SNP) | VAF 13/236 reads (6%) | catalogued as COSV55080475; called by muse, mutect2
- RP1L1 | c.728G>T p.G243V | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV61445906; called by muse, mutect2, varscan2
- RPAP1 | c.542-1G>A p.X181_splice | Splice Site (SNP) | VAF 7/55 reads (13%) | catalogued as COSV58540209; called by muse, mutect2
- RPIA | c.839-1G>T p.X280_splice | Splice Site (SNP) | VAF 24/90 reads (27%) | catalogued as COSV52170146; called by muse, mutect2, varscan2
- RTL9 | c.716C>G p.T239S | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as COSV71825779; called by muse, mutect2, varscan2
- RTN1 | c.2206C>T p.P736S | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50729478; called by muse, mutect2, varscan2
- RYR2 | c.11207C>A p.A3736E | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63679334, COSV63692108; called by muse, mutect2, varscan2
- RYR3 | c.8922G>T p.K2974N (on ENST00000389232; = p.K2975N on NM_001036.6) | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV66776762, COSV66795354; called by muse, mutect2, varscan2
- SACS | c.12853A>T p.S4285C | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.293); catalogued as COSV66541871; called by muse, mutect2, varscan2
- SGMS1 | c.654A>G p.I218M | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.13); catalogued as COSV62370986; called by muse, mutect2, varscan2
- SGSM2 | c.544G>T p.E182* | Nonsense Mutation (SNP) | VAF 15/93 reads (16%) | catalogued as COSV52158934; called by muse, mutect2, varscan2
- SHANK3 | c.1976G>T p.R659M | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV53187664; called by muse, mutect2, varscan2
- SHANK3 | c.1977G>T p.R659S | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.347); catalogued as COSV53187676; called by muse, mutect2, varscan2
- SI | c.2244G>T p.Q748H | Missense Mutation (SNP) | VAF 63/154 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV52284213; called by muse, mutect2, varscan2
- SI | c.1753A>T p.I585F | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV52284226; called by muse, mutect2, varscan2
- SIGIRR | c.1141C>T p.R381W | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as rs1339171572, COSV58986446; called by muse, mutect2
- SIGLEC12 | c.289G>A p.G97R | Missense Mutation (SNP) | VAF 109/272 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV52460368; called by muse, varscan2
- SIRPB1 | c.969G>T p.R323S | Missense Mutation (SNP) | VAF 67/148 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.85); catalogued as COSV53539253; called by muse, mutect2, varscan2
- SLC12A9 | c.1673G>T p.G558V | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745538841, COSV51932682, COSV51934678; called by muse, mutect2, varscan2
- SLC39A12 | c.112G>T p.G38W | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV101069990; called by muse, mutect2, varscan2
- SLC8A3 | c.2129C>A p.A710E (on ENST00000381269 / NM_183002.3; = p.A708E on NM_033262.4) | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as COSV53690533; called by muse, mutect2, varscan2
- SLCO5A1 | c.848C>A p.T283N | Missense Mutation (SNP) | VAF 20/167 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52661591; called by muse, mutect2, varscan2
- SOS2 | c.3622C>A p.P1208T | Missense Mutation (SNP) | VAF 30/198 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV53569190; called by muse, mutect2, varscan2
- SPATA16 | c.1282A>G p.T428A | Missense Mutation (SNP) | VAF 57/136 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV63530319; called by muse, mutect2, varscan2
- SPATC1 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as rs782625052, COSV66299158; called by muse, mutect2
- SPHKAP | c.105C>G p.S35R | Missense Mutation (SNP) | VAF 15/186 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as COSV60883329; called by muse, mutect2
- SPINK5 | c.1564G>T p.G522C | Missense Mutation (SNP) | VAF 33/164 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV56256506; called by muse, mutect2, varscan2
- SPTA1 | c.6250G>T p.D2084Y | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.74); catalogued as COSV63755135; called by muse, mutect2, varscan2
- SPTA1 | c.3193C>A p.R1065S | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT tolerated (0.59); PolyPhen benign (0.006); catalogued as COSV100934682; called by muse, mutect2, varscan2
- STAT6 | c.2009A>G p.Y670C | Missense Mutation (SNP) | VAF 52/223 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as COSV55666721; called by muse, mutect2, varscan2
- SZRD1 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs371668167; called by muse, mutect2, varscan2
- TAAR6 | c.229G>T p.A77S | Missense Mutation (SNP) | VAF 41/145 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.69); catalogued as rs767994339, COSV51583683, COSV51583769; called by muse, mutect2, varscan2
- TACC2 | c.1079G>T p.G360V | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.079); catalogued as COSV57771574; called by muse, mutect2, varscan2
- TCF20 | c.5602G>T p.V1868F | Missense Mutation (SNP) | VAF 56/187 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59492928; called by muse, mutect2, varscan2
- TCOF1 | c.3574G>A p.E1192K (on ENST00000377797 / NM_001135243.1; = p.E1115K on NM_000356.4) | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as rs751297952, COSV60349960; called by muse, mutect2, varscan2
- TENM2 | c.2464C>A p.L822M (on ENST00000518659 / NM_001122679.2; = p.L590M on NM_001080428.3) | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.08); catalogued as COSV69133398; called by muse, mutect2, varscan2
- TENM3 | c.1702A>T p.S568C | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); catalogued as COSV69311304; called by muse, mutect2, varscan2
- THSD7B | c.3847G>T p.G1283* (on ENST00000272643; = p.G1281* on NM_001316349.2) | Nonsense Mutation (SNP) | VAF 9/121 reads (7%) | catalogued as COSV55659168, COSV55687516; called by muse, mutect2
- TMEM161A | c.145C>T p.R49W | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs772837226, COSV50776988; called by muse, mutect2, varscan2
- TMEM200A | c.11C>A p.T4N | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV51654543; called by muse, mutect2, varscan2
- TMEM63B | c.2486A>G p.E829G | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52480096; called by muse, mutect2, varscan2
- TPK1 | c.239G>T p.R80I | Missense Mutation (SNP) | VAF 39/240 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.024); catalogued as COSV63642463; called by muse, mutect2, varscan2
- TREM1 | c.704A>T p.*235Lext*27 | Nonstop Mutation (SNP) | VAF 8/75 reads (11%) | catalogued as COSV55148858; called by muse, mutect2, varscan2
- TRIM11 | c.829G>T p.G277* | Nonsense Mutation (SNP) | VAF 19/52 reads (37%) | catalogued as COSV52857610; called by muse, mutect2, varscan2
- TRIM21 | c.830G>A p.G277E | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); catalogued as rs1240085813, COSV54344757; called by muse, mutect2, varscan2
- TRIM23 | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51552363; called by muse, mutect2, varscan2
- TRIM58 | c.947G>C p.G316A | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.596); catalogued as COSV63570843; called by muse, mutect2
- TRPA1 | c.1657C>G p.H553D | Missense Mutation (SNP) | VAF 96/230 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51564739; called by muse, mutect2, varscan2
- TRRAP | c.5884C>T p.H1962Y (on ENST00000359863 / NM_001244580.1; = p.H1944Y on NM_003496.3) | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62846740; called by muse, mutect2, varscan2
- TSHZ3 | c.250C>G p.R84G | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV53674499; called by muse, mutect2, varscan2
- TTC26 | c.1079C>T p.P360L | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV58272207; called by muse, mutect2, varscan2
- TTN | c.12204_12205insA p.G4069Rfs*32 (on ENST00000591111; = p.G4023Rfs*32 on NM_003319.4) | Frame Shift Ins (INS) | VAF 13/72 reads (18%) | catalogued as COSV100604080; called by mutect2, pindel, varscan2
- UHRF1BP1 | c.2663C>A p.P888H | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.491); catalogued as COSV51956671; called by muse, mutect2, varscan2
- UMOD | c.1182G>A p.T394= | Splice Region (SNP) | VAF 9/44 reads (20%) | catalogued as rs770357364, COSV56776686; called by muse, mutect2, varscan2
- WDR44 | c.1793G>C p.R598P | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.875); catalogued as COSV54162967, COSV54164879; called by muse, mutect2, varscan2
- WDR64 | c.3212T>A p.L1071Q | Missense Mutation (SNP) | VAF 35/145 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV63797010; called by muse, mutect2, varscan2
- WNK3 | c.3989G>T p.G1330V | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.911); catalogued as COSV63614644; called by muse, mutect2, varscan2
- WNK4 | c.2135C>A p.P712Q | Missense Mutation (SNP) | VAF 59/132 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55906172; called by muse, mutect2, varscan2
- WNT3 | c.13C>A p.L5M | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.665); catalogued as rs140453711; called by muse, mutect2, varscan2
- WNT7A | c.921G>T p.M307I | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as COSV53196603; called by muse, mutect2, varscan2
- XIRP2 | c.7873G>T p.V2625F (on ENST00000628543; = p.V2800F on NM_152381.6) | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV54709551; called by muse, mutect2, varscan2
- ZBED9 | c.1240C>T p.P414S | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as COSV71729446; called by muse, mutect2, varscan2
- ZDBF2 | c.3718G>A p.G1240S | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.021); catalogued as rs997213386, COSV65627203; called by muse, mutect2
- ZEB2 | c.1616G>T p.C539F | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV57959480; called by muse, mutect2, varscan2
- ZFHX4 | c.17C>A p.S6Y | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.825); catalogued as COSV51444152; called by muse, mutect2, varscan2
- ZFHX4 | c.7961A>G p.Q2654R | Missense Mutation (SNP) | VAF 26/167 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51444214; called by muse, mutect2, varscan2
- ZFHX4 | c.9508C>A p.P3170T | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.127); catalogued as COSV50641564; called by muse, mutect2
- ZFP57 | c.611G>T p.S204I | Missense Mutation (SNP) | VAF 15/175 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.387); catalogued as rs747717587, COSV65306347; called by muse, mutect2
- ZIC1 | c.1002C>A p.C334* | Nonsense Mutation (SNP) | VAF 22/83 reads (27%) | catalogued as COSV51554806, COSV99292567; called by muse, mutect2, varscan2
- ZMAT1 | c.226G>T p.E76* | Nonsense Mutation (SNP) | VAF 7/20 reads (35%) | catalogued as COSV65658935; called by muse, mutect2, varscan2
- ZNF454 | c.1261T>A p.F421I | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60768957; called by muse, mutect2, varscan2
- ZNF460 | c.824G>A p.S275N | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.267); catalogued as COSV64415826; called by muse, mutect2, varscan2
- ZNF479 | c.1375C>A p.H459N | Missense Mutation (SNP) | VAF 35/159 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as COSV58639818, COSV58643871; called by muse, mutect2, varscan2
- ZNF485 | c.152-1G>T p.X51_splice | Splice Site (SNP) | VAF 14/51 reads (27%) | catalogued as COSV62424567; called by muse, mutect2, varscan2
- ZNF680 | c.728G>T p.C243F | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59016472; called by muse, mutect2, varscan2
- ZNF681 | c.1366G>T p.G456W | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68074528; called by muse, mutect2, varscan2
- ZNF808 | c.84T>A p.D28E | Missense Mutation (SNP) | VAF 42/234 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63120331; called by muse, mutect2, varscan2
- ZNF98 | c.1466C>A p.P489H | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV63337407; called by muse, mutect2, varscan2
- ZSCAN1 | c.640T>G p.W214G | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT tolerated (0.4); PolyPhen benign (0.255); catalogued as COSV56605537; called by muse, mutect2, varscan2
- ANK3 | c.9584del p.G3195Afs*42 | Frame Shift Del (DEL) | VAF 21/125 reads (17%) | called by mutect2, pindel, varscan2
- CALHM2 | c.503dup p.N168Kfs*16 | Frame Shift Ins (INS) | VAF 31/122 reads (25%) | called by mutect2, pindel, varscan2
- CNDP2 | c.927del p.W309Cfs*23 | Frame Shift Del (DEL) | VAF 77/260 reads (30%) | called by mutect2, pindel, varscan2
- FAM114A2 | c.518del p.G173Vfs*5 | Frame Shift Del (DEL) | VAF 8/72 reads (11%) | called by mutect2, pindel
- GPR174 | c.898del p.R300Efs*21 | Frame Shift Del (DEL) | VAF 21/58 reads (36%) | called by mutect2, pindel, varscan2
- HYDIN | c.4801T>A p.F1601I | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.233G>T p.S78I | Missense Mutation (SNP) | VAF 26/272 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.015); called by muse, mutect2
- IGKV1-9 | c.53C>A p.P18Q | Missense Mutation (SNP) | VAF 20/262 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.061); called by muse, mutect2
- IGKV3D-11 | c.191C>A p.P64H | Missense Mutation (SNP) | VAF 8/131 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MDC1 | c.1693del p.V565Yfs*3 | Frame Shift Del (DEL) | VAF 7/71 reads (10%) | called by mutect2, pindel, varscan2
- NPNT | c.149_151del p.R50del | In Frame Del (DEL) | VAF 8/78 reads (10%) | called by mutect2, pindel
- PLEC | c.10403_10411del p.L3468_G3471delinsR (on ENST00000322810 / NM_201380.4; = p.L3358_G3361delinsR on NM_000445.5) | In Frame Del (DEL) | VAF 28/86 reads (33%) | called by mutect2, pindel, varscan2
- SIGLEC12 | c.233_235dup p.T78dup | In Frame Ins (INS) | VAF 54/168 reads (32%) | called by pindel, varscan2
- SUPT20HL2 | c.700C>A p.P234T | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- TNRC6C | c.3638del p.K1213Sfs*58 | Frame Shift Del (DEL) | VAF 20/80 reads (25%) | called by mutect2, pindel, varscan2
- UGT2A3 | c.990dup p.Q331Tfs*23 | Frame Shift Ins (INS) | VAF 61/257 reads (24%) | called by mutect2, pindel, varscan2
- ZNF658 | c.1897A>T p.N633Y | Missense Mutation (SNP) | VAF 72/222 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.495); called by muse, mutect2, varscan2
- ZRANB2 | c.128del p.K43Rfs*2 | Frame Shift Del (DEL) | VAF 18/125 reads (14%) | called by mutect2, pindel, varscan2
- AC090517.4 | c.723T>C p.P241= | Silent (SNP) | VAF 15/86 reads (17%) | catalogued as COSV50997855; called by muse, mutect2, varscan2
- ALPK3 | c.2742G>T p.L914= | Silent (SNP) | VAF 15/80 reads (19%) | catalogued as COSV99360638; called by muse, mutect2, varscan2
- ANGPT1 | c.801A>G p.K267= | Silent (SNP) | VAF 72/150 reads (48%) | catalogued as rs138395811; called by muse, mutect2, varscan2
- C6orf58 | c.990C>A p.S330= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV61666738; called by muse, mutect2, varscan2
- CASP9 | c.492C>T p.L164= | Silent (SNP) | VAF 28/154 reads (18%) | catalogued as COSV61601765; called by muse, mutect2, varscan2
- CDH12 | c.1488C>A p.A496= | Silent (SNP) | VAF 31/218 reads (14%) | catalogued as COSV101202099; called by muse, mutect2, varscan2
- CHD1L | c.2433C>G p.V811= | Silent (SNP) | VAF 23/422 reads (5%) | catalogued as COSV63614419; called by muse, mutect2
- CNGA1 | c.1116C>T p.V372= | Silent (SNP) | VAF 13/261 reads (5%) | catalogued as COSV62054808; called by muse, mutect2
- COL9A2 | c.1854G>T p.G618= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as COSV65623110; called by muse, mutect2, varscan2
- CYSLTR2 | c.708G>T p.S236= | Silent (SNP) | VAF 31/112 reads (28%) | catalogued as COSV56165394, COSV56166153; called by muse, mutect2, varscan2
- DEPDC5 | c.1803C>T p.F601= | Silent (SNP) | VAF 33/131 reads (25%) | catalogued as rs368563183; ClinVar: likely benign; called by muse, mutect2, varscan2
- DHRS7B | c.135C>T p.R45= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as rs764906576, COSV60887999; called by muse, mutect2, varscan2
- EPHA6 | c.2211A>T p.G737= (on ENST00000389672 / NM_001080448.3; = p.G129= on NM_173655.4) | Silent (SNP) | VAF 58/135 reads (43%) | catalogued as COSV67577497; called by muse, mutect2, varscan2
- ESR2 | c.906C>A p.A302= | Silent (SNP) | VAF 24/186 reads (13%) | catalogued as rs1221882618, COSV99963021; called by muse, mutect2, varscan2
- ETHE1 | c.732C>T p.N244= | Silent (SNP) | VAF 31/94 reads (33%) | catalogued as COSV52670225; called by muse, mutect2, varscan2
- ETNK1 | c.489T>G p.L163= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as COSV56886654; called by muse, mutect2, varscan2
- EVC2 | c.258G>T p.V86= | Silent (SNP) | VAF 4/56 reads (7%) | catalogued as COSV60395802; called by muse, mutect2
- FAM161B | c.1143C>T p.I381= (on ENST00000651776; = p.I318= on NM_152445.3) | Silent (SNP) | VAF 10/79 reads (13%) | catalogued as COSV54102715; called by muse, mutect2, varscan2
- FAM47B | c.993C>G p.L331= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as COSV61454662; called by muse, mutect2, varscan2
- FAT3 | c.12870C>T p.P4290= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as COSV53127656; called by muse, mutect2, varscan2
- FEZ1 | c.126C>A p.S42= | Silent (SNP) | VAF 18/116 reads (16%) | catalogued as COSV54029368; called by muse, mutect2, varscan2
- GYS2 | c.1377C>T p.T459= | Silent (SNP) | VAF 19/107 reads (18%) | catalogued as COSV53924646; called by muse, mutect2, varscan2
- ITGA11 | c.1482G>T p.V494= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as rs755339488, COSV59878754, COSV59882457; called by muse, mutect2, varscan2
- ITIH1 | c.1251C>A p.L417= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV56252288, COSV56256008; called by muse, mutect2, varscan2
- JARID2 | c.1389G>T p.A463= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as COSV59191293; called by muse, mutect2, varscan2
- KCNJ6 | c.669G>C p.R223= | Silent (SNP) | VAF 15/100 reads (15%) | catalogued as COSV55716413; called by muse, mutect2, varscan2
- KCNV1 | c.312C>T p.D104= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as COSV52086777; called by muse, mutect2, varscan2
- KLHL1 | c.1776A>T p.T592= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as COSV64774779; called by muse, mutect2, varscan2
- KLHL7 | c.993C>T p.C331= (on ENST00000339077 / NM_001031710.3; = p.C283= on NM_018846.5) | Silent (SNP) | VAF 32/98 reads (33%) | catalogued as rs199531564, COSV59161169; called by muse, mutect2, varscan2
- LOXL1 | c.1443C>T p.C481= | Silent (SNP) | VAF 11/80 reads (14%) | catalogued as COSV56094790; called by mutect2, varscan2
- MAP3K6 | c.3588G>A p.Q1196= | Silent (SNP) | VAF 23/58 reads (40%) | catalogued as COSV58872653; called by muse, mutect2, varscan2
- MORN5 | c.429A>T p.L143= | Silent (SNP) | VAF 47/136 reads (35%) | catalogued as COSV65649092; called by muse, mutect2, varscan2
- MUC16 | c.41241C>G p.L13747= | Silent (SNP) | VAF 34/206 reads (17%) | catalogued as COSV66693438; called by muse, mutect2, varscan2
- MVK | c.519C>T p.C173= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as rs554487221, COSV57331849; ClinVar: likely benign; called by muse, mutect2, varscan2
- MX1 | c.144G>A p.K48= | Silent (SNP) | VAF 33/141 reads (23%) | catalogued as COSV55819685; called by muse, mutect2, varscan2
- NCKAP5L | c.3969C>G p.L1323= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as COSV60130401; called by muse, mutect2
- NECAB2 | c.405C>T p.A135= | Silent (SNP) | VAF 77/193 reads (40%) | catalogued as rs1240304945, COSV59421250; called by muse, mutect2, varscan2
- NES | c.3816C>A p.P1272= | Silent (SNP) | VAF 77/231 reads (33%) | catalogued as COSV63961451; called by muse, mutect2, varscan2
- NKX6-3 | c.765C>T p.F255= (on ENST00000518699 / NM_001364841.2; = p.F125= on NM_152568.3) | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs200542322, COSV72895135; called by muse, mutect2
- NLRP5 | c.2256A>G p.A752= | Silent (SNP) | VAF 58/304 reads (19%) | catalogued as rs1347879080, COSV66765461; called by muse, mutect2, varscan2
- OR12D2 | c.534T>C p.D178= | Silent (SNP) | VAF 23/238 reads (10%) | catalogued as COSV65828505; called by muse, mutect2
- OR2L8 | c.87C>G p.L29= | Silent (SNP) | VAF 54/222 reads (24%) | catalogued as COSV61727139; called by muse, mutect2, varscan2
- OR2T33 | c.255C>A p.T85= | Silent (SNP) | VAF 37/313 reads (12%) | catalogued as rs555852038, COSV58816158, COSV58816808; called by muse, mutect2, varscan2
- PARVA | c.984C>T p.S328= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV58515433; called by muse, mutect2, varscan2
- PCDHGA4 | c.882C>T p.T294= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as rs539292307, COSV53968930; called by muse, mutect2, varscan2
- PCF11 | c.18G>T p.P6= | Silent (SNP) | VAF 25/92 reads (27%) | catalogued as COSV53533034; called by muse, mutect2, varscan2
- PLD3 | c.579G>A p.Q193= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV62925021; called by muse, mutect2
- PRDM9 | c.2208C>A p.L736= | Silent (SNP) | VAF 112/274 reads (41%) | catalogued as rs1427336605, COSV57008138, COSV99690838; called by muse, varscan2
- PTPRF | c.3585G>A p.P1195= | Silent (SNP) | VAF 113/270 reads (42%) | catalogued as rs747346326, COSV63444773; called by muse, mutect2, varscan2
- PTPRT | c.453C>A p.L151= | Silent (SNP) | VAF 34/170 reads (20%) | catalogued as COSV61962190, COSV61991072, COSV62009332; called by muse, mutect2, varscan2
- RSPH6A | c.1149C>T p.V383= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as rs1471834487, COSV55573098; called by muse, mutect2, varscan2
- RYR3 | c.2736A>T p.P912= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV66795347; called by muse, mutect2, varscan2
- SCEL | c.1704A>T p.G568= (on ENST00000349847 / NM_144777.3; = p.G548= on NM_003843.4) | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV62993806; called by muse, mutect2, varscan2
- SCTR | c.1068C>T p.I356= | Silent (SNP) | VAF 22/168 reads (13%) | catalogued as rs1558833877, COSV50028894; called by muse, mutect2, varscan2
- SLC2A13 | c.651A>G p.T217= | Silent (SNP) | VAF 49/221 reads (22%) | catalogued as COSV55120404; called by muse, mutect2, varscan2
- SRRM4 | c.1029G>C p.G343= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV57418968; called by muse, mutect2, varscan2
- STAG3 | c.2121T>G p.S707= | Silent (SNP) | VAF 23/102 reads (23%) | catalogued as COSV57931589; called by muse, mutect2, varscan2
- TG | c.5334T>G p.P1778= | Silent (SNP) | VAF 20/206 reads (10%) | catalogued as COSV55081029; called by muse, mutect2
- TGFBR2 | c.717A>G p.T239= | Silent (SNP) | VAF 35/69 reads (51%) | catalogued as COSV55452039; called by muse, mutect2, varscan2
- TLR4 | c.2331C>T p.T777= (on ENST00000355622 / NM_138554.5; = p.T737= on NM_003266.4) | Silent (SNP) | VAF 21/64 reads (33%) | catalogued as rs957359839, COSV100842842, COSV62923583; called by muse, mutect2, varscan2
- TRDN | c.93G>A p.V31= | Silent (SNP) | VAF 28/100 reads (28%) | catalogued as COSV62124302; called by muse, mutect2, varscan2
- TRIM48 | c.402T>A p.S134= | Silent (SNP) | VAF 19/78 reads (24%) | catalogued as COSV70161885; called by muse, mutect2, varscan2
- TTPAL | c.579T>C p.S193= | Silent (SNP) | VAF 17/95 reads (18%) | catalogued as rs1232140797, COSV52829124; called by muse, mutect2, varscan2
- UBA7 | c.1761A>T p.S587= | Silent (SNP) | VAF 37/85 reads (44%) | catalogued as COSV61092507; called by muse, mutect2, varscan2
- WDR49 | c.1089G>A p.E363= (on ENST00000308378 / NM_001366158.1; = p.E704= on NM_001348951.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 29/110 reads (26%) | catalogued as rs750044931, COSV57710473; called by muse, mutect2, varscan2
- ZDHHC11 | c.18G>T p.G6= | Silent (SNP) | VAF 25/212 reads (12%) | catalogued as COSV52070179; called by muse, mutect2, varscan2
- ZNF135 | c.1776G>T p.S592= (on ENST00000313434 / NM_001289401.2; = p.S604= on NM_003436.4) | Silent (SNP) | VAF 56/113 reads (50%) | catalogued as rs367729073, COSV57883142; called by muse, mutect2, varscan2
- AC073310.1 | n.244A>T | RNA (SNP) | VAF 35/227 reads (15%) | called by muse, mutect2, varscan2
- LINC02145 | n.468A>G | RNA (SNP) | VAF 8/23 reads (35%) | called by muse, mutect2, varscan2
- MORF4 | n.948G>A | RNA (SNP) | VAF 7/59 reads (12%) | called by muse, mutect2, varscan2
- NIN | chr14:50723568 T>A | 3'Flank (SNP) | VAF 12/108 reads (11%) | catalogued as COSV55394942; called by muse, mutect2, varscan2
- OR52A4P | chr11:5120982 A>G | 3'Flank (SNP) | VAF 12/69 reads (17%) | called by muse, mutect2, varscan2
- RPS26P15 | n.274C>A | RNA (SNP) | VAF 18/107 reads (17%) | called by muse, mutect2, varscan2
- USP17L30 | chr4:9359326 T>C | 5'Flank (SNP) | VAF 18/240 reads (8%) | catalogued as rs748939163; called by muse, mutect2
